Somatic mutation profile of tumor specimen TCGA-2G-AAG6-01A (aliquot TCGA-2G-AAG6-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAG6, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, benign; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 24.8 years (9,071 days).
Specimen TCGA-2G-AAG6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6315e26c-e3ed-4f50-b606-503b596c5f62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAG6-10A (Blood Derived Normal), aliquot TCGA-2G-AAG6-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1b81712-f96f-4db2-be00-483428f40cf9

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND7 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.438); catalogued as rs1380869064; called by muse, mutect2, varscan2
- CSF1 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761742218; called by muse, mutect2, varscan2
- SETX | c.7446G>C p.E2482D | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs748683260; called by muse, mutect2, varscan2
- COL8A2 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); called by muse, mutect2
- HECTD4 | c.10288A>G p.I3430V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MORN1 | c.1463G>A p.S488N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PBRM1 | c.1248dup p.Y417Ifs*3 | Frame Shift Ins (INS) | VAF 40/138 reads (29%) | called by mutect2, pindel, varscan2
- VPS37B | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2
- ZNF729 | c.3283A>T p.K1095* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- CACNA1A | c.1596C>A p.S532= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- CXXC1 | c.1098C>A p.A366= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- LMAN1L | c.576C>T p.T192= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
